Somatic mutation profile of tumor specimen 0DWGJW from CCDI case PBCNNJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 16.7 years (6,089 days).
Specimen 0DWGJW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4fe25d5-624e-4ae9-83a9-d8735a526859.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWGJ2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cadd1497-5b76-4a0c-98f1-af9006b1c048

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, In Frame Ins 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1914_1915insGTT p.A638_T639insV (on ENST00000288602 / NM_001374244.1; = p.A598_T599insV on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Ins (INS) | VAF 135/300 reads (45%) | catalogued as COSV56086959, COSV56201191; called by mutect2, pindel, varscan2
- COL4A6 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 124/384 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP2B3 | c.2235C>T p.G745= | Silent (SNP) | VAF 147/447 reads (33%) | called by muse, mutect2, varscan2
- TTLL2 | c.1536G>A p.R512= | Silent (SNP) | VAF 13/260 reads (5%) | catalogued as COSV53445269; called by muse, mutect2
